Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PN, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PN-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

ICD-0-3

Carcinosarcoma, NOS
8980/3

Site:

Endometrium, C54.1
12/14/12 Jm

Diagnosis:

A: Uterus, bilateral tubes and ovaries, total abdominal
hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Posterior endometrium.

Histologic type: Carcinosarcoma, homologous type.

Histologic grade (FIGO): Grade 3.

Extent of invasion: Myometrial invasion with lymphovascular
space involvement.

Myometrial invasion: Inner half.

Depth: 5 mm Wall thickness: 15 mm Percent: 33%

Serosal involvement: Absent.

Lower uterine segment involvement: Absent.

Cervical involvement: Absent.

Adnexal involvement: Absent [See comment].

Cervical/vaginal margin and distance: Widely negative.

Lymphovascular space invasion: Present.

Regional lymph nodes (see Parts B-C):

Total number involved: 3

Total number examined: 20

Other pathologic findings:

- Cervix: Nabothian cysts and chronic inflammation.
- Endometrium: Mixed endometrial/endocervical polyp and background atrophic pattern with breakdown.
- Myometrium: Multiple leiomyomas up to 1.9 cm.
- Ovary, right: Benign inclusion cysts and age related changes.
- Ovary, left: Focal calcification with associated inflammation, benign inclusion cysts and age related changes.
- Fallopian tubes, bilateral: Unremarkable.

[page 2 of 5]
Tumor estrogen and progesterone receptor immunohistochemistry results (A14):
Estrogen receptor: Weakly positive in epithelial component only, 1+, 75%
Progesterone receptor: Positive in epithelial component only, 2+, 50%

AJCC Pathologic Stage: pT1a pN1 pMX
FIGO (2008 classification) Stage grouping: IIIC1
Note: These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

B: Lymph nodes, left pelvic, regional dissection:
- Three of fifteen lymph nodes positive for metastatic malignancy (0/15) [See comment].
- The metastatic foci consist of single cells and small (<5 cells) groups consistent with micrometastases from the epithelial component of the carcinosarcoma.

C: Lymph node, right pelvic, regional dissection:
- Five lymph nodes negative for malignancy (0/5).

Comment:

Immunohistochemical stains were performed on blocks A17, B1, B3 and B4, with appropriate controls. Block A17 contains the left ovary and shows a single focus of parenchymal calcification surrounded by mildly atypical cells which are morphologically most consistent with histiocytes and do not resemble the patient's endometrial tumor. CD68, inhibin and pan-cytokeratin (AE1/AE3), performed on block A17, are non-contributory due to loss of the focus on further sectioning. Blocks B1, B3 and B4 contain left pelvic lymph nodes with rare foci of atypical single cells and groups which stain positive for pan-cytokeratin (AE1/AE3) and negative for desmin, consistent with the above diagnosis.

Intraoperative Consult Diagnosis:
A frozen section was requested by Dr.

FSA1: Uterus, cervix, bilateral tubes and ovaries, endometrium, total abdominal hysterectomy
- Poorly differentiated malignancy, defer to permanent
- Differential diagnosis includes leiomyosarcoma vs. MMMT
- No definite malignant glandular component identified

[page 3 of 5]
Drs.

Frozen Section Pathologist:, MD

Clinical History:

year-old female with a uterine sarcoma

Gross Description:

Specimen A:

Received is one appropriately labeled container.

Adnexa: bilateral tubes and ovaries are present

Weight: 935 g

Shape: irregular

Dimensions:

height: 19.0 cm

anterior to posterior: 7.5 cm

breadth at fundus: 12.2 cm

Serosa: tan-pink smooth and glistening

Cervix: the cervix measures 3.5 cm in diameter with a patent cervical os

length of endocervical canal: 2.3 cm

ectocervix: tan-white smooth and glistening

endocervix: tan-white and trabeculated

Endometrium:

length of endometrial cavity: 11.2 cm

width of endometrial cavity at fundus: 4.2 cm

thickness of endometrial lining: 0.1 cm

other findings: the endometrium is tan-white and appears flattened or effaced by a large mass within the endometrial cavity

Myometrium:

thickness of wall: 3.2 cm

other findings: There is a large mass which appears to be arising from the posterior myometrium measuring 14.5 x 13.7 x 7.8 cm. The mass appears to have both solid tan-white to yellow components as well as cystic areas. There are focal areas of hemorrhage and extensive necrosis present within the mass. The mass grossly appears to be at least 1.5 cm away from the posterior serosal surface. There are multiple additional tan-white nodules within the myometrium ranging in largest diameter from 0.7 to 1.9 cm. The cut surface of these nodules are tan-white firm and whorled in appearance.

[page 4 of 5]
Adnexa:

Right ovary:

measurement: 2.5 x 1.0 x 0.5 cm

external surface: tan-white and cerebriform

cut surface: tan-white and unremarkable

Right fallopian tube:

measurement: 3.0 cm in length and 0.6 cm in diameter sectioning

reveals a patent lumen

other findings:

Left ovary:

measurement: 2.5 x 1.2 x 0.5 cm

external surface: tan-white and cerebriform

cut surface: tan-white and unremarkable

Left fallopian tube:

measurement: length 2.8 cm, diameter is 0.6 cm

other findings: sectioning reveals a patent lumen

Other comments: none

Tissue submitted for special investigations: tumor was given to tissue procurement

Block Summary:

FSA1 - representative section of mass

A2-A3 - anterior cervix and lower uterine segment

A4-A5 - anterior mid corpus, bisected

A6 - anterior upper corpus

A7-A8 - posterior cervix and lower uterine segment

A9-A10 - posterior mid corpus

A11 - posterior upper corpus

A12 - mass with underlying myometrium

A13-A14 - mass in relationship to serosa

A15 - right ovary

A16 - right fallopian tube with fimbria

A17 - left ovary

A18 - left fallopian tube with fimbria

A19-A25 - representative sections of mass, approximately every 1 cm

Specimen B is received in a formalin filled container labeled with the patient's name and additionally "left pelvic nodes". An aggregate of yellow-tan fibrofatty tissue measuring 3.0 x 2.6 x 1.0 cm. The tissue is bisected for lymph node candidates. Twelve lymph node candidates are found ranging in largest diameter from 0.5 to 2.0 cm.

Block Summary:

B1 - three lymph node candidates

[page 5 of 5]
- B2 - five lymph node candidates
- B3 - two lymph node candidates
- B4 - two lymph node candidates
- B5 - remaining tissue,

Specimen C is received in a formalin filled container labeled with the patient's name and additionally "right pelvic node" is an aggregate of yellow-tan fibrofatty tissue measuring 3.8 x 2.5 x 1.0 cm. The tissue is dissected for lymph node candidates. Five lymph node candidates are found ranging in large diameter from 0.6 to 1.5 cm.

Block Summary:

- C1 - three lymph node candidates
- C2 - one lymph node candidate
- C3 - one lymph node candidate bisected
- C4 - remaining tissue,

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

W 12/13/12

	Yes	No
Quality		X
Proficiency		X
Accuracy		X
Reliability		X
Reproducibility		X
Repeatability		X
Recovery		X
Reference Range		X
Reference Interval		X
Reference Value		X
Reference Unit		X
Reference Method		X
Reference Material		X
Reference Source		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X
Reference Date		X
Reference Time		X
Reference Location		X
Reference Person		X
Reference Event		X
Reference Result		X
Reference Comment		X
Reference Signature		X

Source: NCI Genomic Data Commons file 6beeaa72-865c-4ca3-97f2-30a02565a1c1 (TCGA-N8-A4PN.DF47A171-5805-4D4A-BB30-C686434323B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).